Somatic mutation profile of tumor specimen MBCProject_0246_T1_WES (aliquot MBCProject_0246_T1_WES_1) from CMI case MBCProject_0246, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.1 years (17,916 days).
Specimen MBCProject_0246_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d96a0a-63fd-4841-96c3-b16570f45333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0246_SALIVA (Saliva), aliquot MBCProject_0246_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f1fdc22-abcc-4a51-a1f4-f2d2a44cc922

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 5, Intron 3, 5'UTR 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 24/442 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- DYNC1H1 | c.10900C>G p.L3634V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64138379; called by muse, mutect2
- GRM1 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 18/267 reads (7%) | catalogued as COSV51235719; called by muse, mutect2
- HMCN1 | c.13789G>A p.E4597K | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs56253530, COSV54902736, COSV54921294; called by muse, mutect2
- LIX1 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs139105148; called by muse, mutect2, varscan2
- OR5L1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs138368201; called by muse, mutect2
- PRPF40B | c.2532G>T p.W844C (on ENST00000380281; = p.W831C on NM_012272.3) | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99526621; called by muse, mutect2
- SMCHD1 | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as rs1436761397; called by muse, mutect2
- ARSJ | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- MPP6 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2
- NET1 | c.521G>A p.R174K (on ENST00000355029 / NM_001047160.3; = p.R120K on NM_005863.5) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCID2 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- PIK3C2A | c.3350T>C p.V1117A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2
- PLVAP | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2
- PRRC2C | c.8107A>T p.K2703* (on ENST00000367742; = p.K2701* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- RYR1 | c.14753A>C p.D4918A | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SDK2 | c.2381C>A p.P794H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SETBP1 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMEM67 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- ZNF514 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKH | c.402C>T p.Y134= | Silent (SNP) | VAF 57/493 reads (12%) | called by muse, mutect2, varscan2
- CIAO3 | c.1176C>G p.V392= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- COL5A1 | c.633C>T p.I211= | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- FAT4 | c.5517C>G p.P1839= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- HSP90AA1 | c.150G>C p.L50= | Silent (SNP) | VAF 20/335 reads (6%) | catalogued as COSV100085429; called by muse, mutect2
- OR10Q1 | c.360G>A p.A120= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs780016831, COSV100372396, COSV57469778; called by mutect2, varscan2
- CR1 | c.487+12119G>T | Intron (SNP) | VAF 100/509 reads (20%) | called by muse, mutect2, varscan2
- DLGAP5 | c.2419-178G>C | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- EIF4G1 | c.537+10A>C | Intron (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2
- KRTAP2-2 | c.*62G>T | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, varscan2
- OR11H6 | chr14:20229621 G>A | 3'Flank (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- SLC22A15 | c.-55G>C | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
